Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9K6, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9K6-01A (Primary Tumor).

ICD-O-3
Carcinoma, papillary renal cell 8260/3
Site: R Kidney N02.64.9
5/6/13/14

Papillary Renal Cell Carcinoma, Type I, moderately differentiated. The tumor presents as a multi-focal one.

Stage: pT1a (multifocal), R0

Grade: GII

ICD-O-Code: 8260/3

Laterality = (R)

Source: NCI Genomic Data Commons file ec5bbfff-bef7-480f-aef7-c7020c3535bf (TCGA-5P-A9K6.6B3A5E0D-BFF2-4386-A9F9-1DB99DEDC3F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).